Gene-level copy-number profile of tumor specimen ALCH-B3B3-TTP1-A from ALCHEMIST case ALCH-B3B3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,307 days).
Specimen ALCH-B3B3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file faf34a2c-f26a-43da-9794-03d4f961ec88.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3B3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/0ec5ef26-9ccb-4d41-ba14-77a5dcb3a0c1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 18,781; copy number 2: 38,617; copy number 3: 759; copy number 4: 18; copy number 5: 4; copy number 7: 5; copy number 8: 32; copy number 9: 25; copy number 10: 24; copy number 11: 11; copy number 12: 6; copy number 16: 25; copy number 19: 5; copy number 21: 10; copy number 22: 34; copy number 26: 22.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,081,831–130,113,227, 3 genes (within-gene range 0–1): ALG1L2, LINC02014, FAM86HP.
- chr7:101,085,481–101,097,967, 1 gene: TRIM56.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr15:64,701,248–64,775,589, 3 genes (within-gene range 0–1): AC100830.1, RBPMS2, MIR1272.
- chr15:76,174,891–76,181,486, 1 gene (within-gene range 0–1): AC091100.1.
- chr18:37,234,119–37,762,131, 7 genes (within-gene range 0–1): AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr22:21,290,760–21,325,042, 3 genes (within-gene range 0–1): BCRP6, FAM230H, AP000552.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 203 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:795,606–850,986, 2 genes, copy number 5 (within-gene range 4–5): ZDHHC11, SPCS2P3.
- chr5:979,365–981,300, 1 gene, copy number 5: AC122719.2.
- chr7:79,452,877–80,391,474, 10 genes, copy number 11 (within-gene range 1–11): MAGI2-AS3, NUP35P2, RNA5SP234, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P.
- chr7:80,377,554–80,377,835, 1 gene, copy number 11 (within-gene range 1–11): SNRPBP1.
- chr12:54,230,942–54,648,493, 25 genes, copy number 9: CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD.
- chr12:63,558,913–63,795,718, 5 genes, copy number 7 (within-gene range 3–7): DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1.
- chr12:64,759,496–64,977,509, 1 gene, copy number 8 (within-gene range 3–8): AC078815.1.
- chr12:64,883,394–73,208,317, 153 genes, copy number 8–26 (broad region; genes not listed).
- chr14:105,583,731–105,601,728, 2 genes, copy number 12 (within-gene range 1–12): IGHA2, IGHE.
- chr14:105,621,116–105,621,180, 1 gene, copy number 5: MIR8071-1.
- chr22:21,114,607–21,124,451, 1 gene, copy number 8 (within-gene range 3–8): AP000550.1.
- chr22:21,370,064–21,371,945, 1 gene, copy number 16: AP000552.1.

Autosomal genes at a single copy (total copy number 1): 18,672. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
